MMRF case MMRF_1735 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3ae2782f-6478-4c9b-9310-655a9961c1f8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.5 years (23,572 days); ISS stage: II; Days to last known disease status: 1,155 days (3.2 years); Days to last follow up: 1,155 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 107 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 241 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 241 days; Days to treatment end: 507 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 516 days (1.4 years); Days to treatment end: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 516 days (1.4 years); Days to treatment end: 1,011 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 718 days (2.0 years); Days to treatment end: 764 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.8 mg/dL; Immunoglobulin G 59.9 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 3.24 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 10.4 g/dL; Glucose 5.34 mmol/L.
- Day 101: Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 34.5 ×10⁹/L; Absolute Neutrophil 26.9 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 33 g/L; Total Protein 7.2 g/dL; Glucose 7.65 mmol/L.
- Day 176: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 269: M Protein 0.5 g/dL; Hemoglobin 7.69 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.89 mmol/L.
- Day 358: M Protein 0.6 g/dL; Hemoglobin 8.43 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.6 mmol/L.
- Day 453 (ECOG 0): M Protein 0.7 g/dL; Beta 2 Microglobulin 2.28 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 8.2 g/dL; Glucose 5.34 mmol/L.
- Day 521: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.1 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.56 µg/mL; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 638: M Protein 0.4 g/dL; Hemoglobin 8.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 7.43 mmol/L.
- Day 718 (ECOG 1): M Protein 0.3 g/dL; Hemoglobin 7.94 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 8.58 mmol/L.
- Day 821 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.66 mg/dL; Hemoglobin 7.38 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 899 (ECOG 0): M Protein 0.4 g/dL; Hemoglobin 6.51 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 365 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.45 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 983 (ECOG 1): M Protein 0.3 g/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 29 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 1,071 (ECOG 1): M Protein 0.3 g/dL; Hemoglobin 8.62 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 7.48 mmol/L.
- Day 1,155 (ECOG 1): M Protein 0.5 g/dL; Hemoglobin 7.13 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 30 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 110 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1735_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1735_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
